Somatic mutation profile of tumor specimen TCGA-AX-A0J0-01A (aliquot TCGA-AX-A0J0-01A-11D-A117-09) from TCGA case TCGA-AX-A0J0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 47.8 years (17,466 days).
Specimen TCGA-AX-A0J0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfaec359-bbc0-40b4-bdc9-c80ee478a4a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A0J0-11A (Solid Tissue Normal), aliquot TCGA-AX-A0J0-11A-11D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fdba8ea-d0e0-4650-b9a1-c2c6adc77d34

The open-access MAF lists 8,630 somatic variants for this specimen: 7,032 protein-altering or splice-affecting, 1,415 silent, 183 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,836, Silent 1,415, Nonsense Mutation 972, Splice Site 106, Intron 72, RNA 58, Splice Region 50, Frame Shift Ins 48, 3'UTR 17, 3'Flank 14, 5'UTR 13, Nonstop Mutation 11.

Variants (750 of 8,630; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs387907208, CM124860, COSV53963892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDOB | c.888G>A p.W296* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs1057517133, COSV66397838; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP8B1 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | catalogued as rs515726137, CM043824, COSV52172870, COSV52176779; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as rs80357391, COSV100523273, COSV58792690; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779823379, CM120107, COSV67502170; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 46/91 reads (51%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, varscan2
- COL1A1 | c.472-1G>T p.X158_splice | Splice Site (SNP) | VAF 27/65 reads (42%) | catalogued as rs72667020, CS971667, COSV56806431; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.8716G>T p.E2906* | Nonsense Mutation (SNP) | VAF 113/293 reads (39%) | catalogued as rs863225153, COSV57063378; ClinVar: pathogenic; called by muse, varscan2
- CPS1 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as rs759201450, COSV51805317, COSV99028158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1081C>T p.R361C (on ENST00000399959; = p.R362C on NM_001356.5) | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs797045026, CM158053, COSV67863880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.179T>G p.M60R | Missense Mutation (SNP) | VAF 37/79 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV57247351, COSV57256248; called by muse, mutect2, varscan2
- F9 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as rs137852261, CM940671, COSV54378604; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN2 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs200060005, CM1412995, COSV52489870, COSV52518440; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1973G>A p.R658Q (on ENST00000281708 / NM_001349798.2; = p.R578Q on NM_018315.5) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs759610249, COSV55905466; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1645A>C p.N549H | Missense Mutation (SNP) | VAF 102/240 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519045, CM020140, COSV60640393, COSV60650624; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 65/138 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- GFM2 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs761283105, COSV57191541; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GNE | c.922C>T p.R308C (on ENST00000396594 / NM_001128227.3; = p.R277C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs762106720, CM086833, CM139083, COSV64951631; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LARS2 | c.*377C>T | 3'UTR (SNP) | VAF 60/124 reads (48%) | catalogued as rs774649299, COSV55528687; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MED13L | c.4387G>A p.G1463R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1555243607, COSV56122690; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as rs398123275, CM970981, COSV60335631; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 57/128 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868238523, COSV62337400, COSV62339851, COSV62344458; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OCRL | c.2530C>T p.R844* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | catalogued as rs387906484, CM930520, COSV63981130; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX2 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 45/96 reads (47%) | catalogued as rs61752124, CM981684, COSV63813349; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>T p.T1025S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen benign (0.207); catalogued as CM126696, COSV55873252, COSV55911053, COSV55955422; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 36/80 reads (45%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 42/95 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- POU1F1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as rs104893760, CM950968, COSV55461353; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 32/83 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RB1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 105/121 reads (87%) | catalogued as rs121913296, CM961221, COSV57300832; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.10939G>T p.E3647* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as rs1156566314, COSV66538422, COSV66541147; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SAMD9 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs1186536794, COSV66076161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SBF2 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as rs1413469900, COSV56302192; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SDHA | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 63/131 reads (48%) | catalogued as rs771328239, COSV53769941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SUCLA2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 128/293 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs370898100, COSV66222419; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 19/150 reads (13%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TCOF1 | c.4365dup p.E1456Rfs*15 (on ENST00000377797 / NM_001135243.1; = p.E1379Rfs*15 on NM_000356.4) | Frame Shift Ins (INS) | VAF 52/139 reads (37%) | catalogued as rs587776585; ClinVar: pathogenic; called by mutect2, varscan2
- TSC1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060505021, COSV53766018, COSV53768396; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TTN | c.56572C>T p.R18858* (on ENST00000591111; = p.R11434* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs869312112, CM121824, COSV59933111; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1484+2T>C p.X495_splice (on ENST00000373993 / NM_138932.2; = p.X487_splice on NM_014576.4) | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV50975941; called by muse, mutect2, varscan2
- A1CF | c.1243G>T p.G415* (on ENST00000373993 / NM_138932.2; = p.G407* on NM_014576.4) | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99255708, COSV99256733; called by muse, mutect2
- A2M | c.3942G>T p.M1314I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV59388356; called by muse, mutect2, varscan2
- A2M | c.3744C>A p.F1248L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59388364; called by muse, mutect2, varscan2
- A2M | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs774076635, COSV59382509; called by muse, mutect2, varscan2
- A2ML1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.913); catalogued as COSV55298126; called by muse, mutect2
- AAGAB | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56017291; called by muse, mutect2, varscan2
- ABCA1 | c.5320A>G p.N1774D | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66067491; called by muse, mutect2, varscan2
- ABCA1 | c.4909A>G p.N1637D | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66067495; called by muse, mutect2, varscan2
- ABCA1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs189206655, COSV66064966; called by muse, mutect2, varscan2
- ABCA10 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52221333, COSV52222468; called by muse, mutect2, varscan2
- ABCA12 | c.3091G>T p.A1031S (on ENST00000272895 / NM_173076.3; = p.A713S on NM_015657.3) | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55963154, COSV55963327; called by muse, varscan2
- ABCA12 | c.3003G>T p.K1001N (on ENST00000272895 / NM_173076.3; = p.K683N on NM_015657.3) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.785); catalogued as COSV55956064, COSV55963345; called by muse, varscan2
- ABCA12 | c.2725G>A p.D909N (on ENST00000272895 / NM_173076.3; = p.D591N on NM_015657.3) | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as rs767059932, COSV55963360; called by muse, mutect2, varscan2
- ABCA12 | c.1444G>A p.E482K (on ENST00000272895 / NM_173076.3; = p.E164K on NM_015657.3) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as rs150321357; called by muse, mutect2, varscan2
- ABCA13 | c.5797A>C p.N1933H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV70032487; called by muse, mutect2, varscan2
- ABCA13 | c.6784G>T p.D2262Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV70032492; called by muse, mutect2, varscan2
- ABCA13 | c.6913G>T p.D2305Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs776363780, COSV71284067; called by muse, varscan2
- ABCA13 | c.7546G>A p.A2516T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.779); catalogued as COSV71290208; called by muse, mutect2, varscan2
- ABCA13 | c.8967G>T p.K2989N | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as COSV71285627; called by muse, mutect2, varscan2
- ABCA13 | c.10124G>T p.R3375I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV71290209; called by muse, mutect2, varscan2
- ABCA13 | c.10627G>A p.E3543K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV71292558; called by muse, mutect2
- ABCA5 | c.3910G>T p.D1304Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV67017335; called by muse, mutect2, varscan2
- ABCA5 | c.3394A>C p.N1132H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV67017342; called by muse, mutect2, varscan2
- ABCA5 | c.2788A>C p.S930R | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV67017345; called by muse, mutect2, varscan2
- ABCA5 | c.1334G>T p.R445I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs776278452, COSV67017350; called by muse, mutect2, varscan2
- ABCA5 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67017361; called by muse, mutect2, varscan2
- ABCA5 | c.372C>A p.S124R | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV67017365; called by muse, mutect2, varscan2
- ABCA6 | c.3962C>G p.P1321R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.813); catalogued as rs776865215, COSV99446205, COSV99446803; called by muse, mutect2
- ABCA8 | c.2900G>A p.R967K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs758123773, COSV52204082; called by muse, mutect2, varscan2
- ABCA8 | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as COSV99285383; called by muse, mutect2
- ABCA8 | c.693T>G p.I231M | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.506); catalogued as COSV99285385; called by muse, mutect2
- ABCA8 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52201379; called by muse, mutect2
- ABCA9 | c.4010A>C p.K1337T | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV60626533; called by muse, mutect2, varscan2
- ABCA9 | c.3285G>T p.E1095D | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV60626543; called by muse, varscan2
- ABCA9 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs756457606, COSV60626563; called by muse, mutect2, varscan2
- ABCA9 | c.879A>C p.Q293H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV60626576; called by muse, mutect2, varscan2
- ABCB1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 40/74 reads (54%) | catalogued as rs1222604496, COSV55945529; called by muse, varscan2
- ABCB1 | c.118-1G>T p.X40_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as COSV55954256; called by muse, mutect2, varscan2
- ABCB11 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55593669; called by muse, mutect2, varscan2
- ABCB4 | c.3520A>T p.R1174* (on ENST00000265723 / NM_018849.3; = p.R1167* on NM_000443.4) | Nonsense Mutation (SNP) | VAF 36/68 reads (53%) | catalogued as COSV55936326, COSV55936831; called by muse, mutect2, varscan2
- ABCB4 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as COSV55936843; called by muse, mutect2, varscan2
- ABCB4 | c.2701G>T p.E901* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as COSV55934686, COSV55936859; called by muse, mutect2, varscan2
- ABCB4 | c.2422A>T p.N808Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55936876; called by muse, mutect2, varscan2
- ABCB4 | c.322A>T p.I108F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV55936885; called by muse, mutect2, varscan2
- ABCB4 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs534390925, COSV55936901; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, varscan2
- ABCB5 | c.1838G>A p.R613Q (on ENST00000404938 / NM_001163941.2; = p.R168Q on NM_178559.6) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1187222290, COSV51706928; called by muse, mutect2, varscan2
- ABCB5 | c.3730C>T p.R1244* (on ENST00000404938 / NM_001163941.2; = p.R799* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as rs752941625, COSV51706146; called by muse, mutect2, varscan2
- ABCB7 | c.2169G>T p.K723N (on ENST00000373394 / NM_001271696.3; = p.K724N on NM_004299.6) | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV53721769; called by muse, mutect2
- ABCB7 | c.1154T>C p.F385S (on ENST00000373394 / NM_001271696.3; = p.F386S on NM_004299.6) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53720758; called by muse, mutect2, varscan2
- ABCC11 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs577177114, COSV62323951; called by muse, mutect2, varscan2
- ABCC12 | c.3667G>A p.D1223N | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373791056, COSV60914729; called by muse, mutect2, varscan2
- ABCC12 | c.3083G>T p.R1028I | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs200089399; called by muse, mutect2, varscan2
- ABCC12 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 27/269 reads (10%) | catalogued as COSV60911484; called by muse, mutect2, varscan2
- ABCC12 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs142478393; called by muse, mutect2, varscan2
- ABCC2 | c.2473C>A p.L825I | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64986792; called by muse, mutect2, varscan2
- ABCC4 | c.3243A>C p.K1081N | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65314124; called by muse, mutect2, varscan2
- ABCC5 | c.1149A>C p.K383N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99656684; called by muse, mutect2
- ABCC6 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1360228269, COSV99228496; called by muse, mutect2
- ABCC8 | c.4054C>T p.R1352C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434876771, COSV56852264; called by muse, mutect2, varscan2
- ABCC8 | c.2697C>A p.I899= | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as COSV56852277; called by muse, mutect2, varscan2
- ABCC8 | c.2389C>T p.R797W | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142620721, CM131659; called by muse, mutect2, varscan2
- ABCC8 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs950691063, COSV56852297; called by muse, mutect2, varscan2
- ABCC9 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53975580; called by muse, mutect2, varscan2
- ABCD2 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV58052103; called by muse, varscan2
- ABCD3 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 46/95 reads (48%) | catalogued as COSV64642479; called by muse, mutect2, varscan2
- ABCD4 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778062723, COSV53990914; called by muse, mutect2, varscan2
- ABCF3 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53048726; called by muse, mutect2, varscan2
- ABCG2 | c.993A>T p.K331N | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52946883; called by muse, varscan2
- ABCG2 | c.482T>G p.I161S | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs564525442, COSV52946896; called by muse, mutect2, varscan2
- ABCG4 | c.1188C>A p.F396L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56644022; called by muse, mutect2, varscan2
- ABCG5 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV53211515; called by muse, mutect2, varscan2
- ABCG8 | c.1832G>T p.R611I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV55393098, COSV55396475; called by muse, mutect2, varscan2
- ABI2 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 58/117 reads (50%) | catalogued as COSV53693524; called by muse, mutect2, varscan2
- ABI3BP | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs770109610, COSV52528036; called by muse, mutect2, varscan2
- ABL2 | c.1979G>T p.R660I (on ENST00000502732 / NM_007314.4; = p.R645I on NM_005158.5) | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV61016382; called by muse, mutect2, varscan2
- ABLIM3 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as rs1421226226, COSV58644835; called by muse, mutect2, varscan2
- ABO | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs782069936, COSV101505950, COSV101505976; called by muse, mutect2
- ABRAXAS1 | c.279A>C p.K93N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV58949126; called by muse, mutect2, varscan2
- AC005324.2 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV60887181; called by muse, mutect2, varscan2
- AC008397.2 | c.1964G>T p.R655I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV53207687; called by muse, mutect2, varscan2
- AC018630.4 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | PolyPhen benign (0.135); catalogued as COSV67857315; called by muse, mutect2, varscan2
- AC090517.4 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1426149568, COSV50997871; called by muse, mutect2, varscan2
- AC092143.1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59248071; called by muse, mutect2, varscan2
- AC098582.1 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 51/112 reads (46%) | catalogued as COSV52021352; called by muse, varscan2
- AC100868.1 | c.1506A>C p.R502S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51844787; called by muse, mutect2, varscan2
- AC131160.1 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.514); catalogued as rs200895198, COSV100590603; called by muse, mutect2, varscan2
- AC132217.2 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100323995; called by muse, mutect2
- AC136428.1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 64/89 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs1314577587, COSV71169191; called by muse, varscan2
- ACACB | c.1337G>T p.R446I | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV58128531; called by muse, mutect2, varscan2
- ACAD10 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV58158635; called by muse, varscan2
- ACAD10 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as COSV100564055; called by muse, varscan2
- ACAD9 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs573257268, COSV58306733; called by muse, mutect2, varscan2
- ACADL | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV52053867; called by muse, mutect2, varscan2
- ACAP1 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV50136830; called by muse, mutect2, varscan2
- ACAP1 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV50136862; called by muse, mutect2, varscan2
- ACAP2 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV58752843; called by muse, mutect2, varscan2
- ACAT1 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 44/102 reads (43%) | catalogued as rs748425041, COSV54921285; called by muse, mutect2, varscan2
- ACBD5 | c.1433C>A p.A478E (on ENST00000375888 / NM_001352568.1; = p.A469E on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV65520022; called by muse, mutect2, varscan2
- ACBD5 | c.653-1G>T p.X218_splice (on ENST00000375888 / NM_001352568.1; = p.X209_splice on NM_145698.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 62/141 reads (44%) | catalogued as COSV65520032; called by muse, mutect2, varscan2
- ACCSL | c.563G>T p.R188I | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66581551; called by muse, mutect2, varscan2
- ACE | c.2767G>T p.E923* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as COSV52008421, COSV52014015; called by muse, mutect2, varscan2
- ACE2 | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as rs773848804, COSV53024902; called by muse, mutect2, varscan2
- ACE2 | c.391A>C p.K131Q | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV53025551; called by muse, varscan2
- ACO1 | c.1048T>C p.S350P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV59380952; called by muse, mutect2, varscan2
- ACOT12 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 97/215 reads (45%) | catalogued as rs780095623, COSV56892749; called by muse, mutect2, varscan2
- ACOT2 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs749656008, COSV53150703; called by mutect2, varscan2
- ACSL1 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 31/67 reads (46%) | catalogued as rs1361601006, COSV55660967; called by muse, mutect2, varscan2
- ACSL3 | c.1478A>C p.N493T | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV62483054; called by muse, varscan2
- ACSL4 | c.358C>A p.L120I (on ENST00000340800 / NM_022977.2; = p.L79I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV61614846; called by muse, mutect2, varscan2
- ACSL6 | c.1696G>A p.E566K (on ENST00000379240; = p.E591K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57300228; called by muse, mutect2, varscan2
- ACSM1 | c.1256G>T p.R419I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54636989; called by muse, mutect2, varscan2
- ACSM1 | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSM2B | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.744); catalogued as COSV61658415; called by muse, mutect2, varscan2
- ACSM2B | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV61656870, COSV61658390; called by muse, mutect2, varscan2
- ACSM3 | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55502082; called by muse, mutect2, varscan2
- ACSM5 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV59372545; called by muse, mutect2, varscan2
- ACTA2 | c.844A>G p.N282D | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.311); catalogued as COSV56516944; called by muse, mutect2, varscan2
- ACTC1 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV51759675; called by muse, varscan2
- ACTC1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1437269590, COSV51757644, COSV99291859; called by muse, varscan2
- ACTN2 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs1057522840, COSV63975938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTRT1 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64419616; called by muse, mutect2, varscan2
- ACVR1B | c.715C>A p.R239S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57777906, COSV99231572; called by muse, mutect2, varscan2
- ADAD1 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV56644384; called by muse, mutect2, varscan2
- ADAL | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as rs1275397513, COSV67500713; called by muse, mutect2, varscan2
- ADAM10 | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV53052302; called by muse, mutect2, varscan2
- ADAM11 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1297795835, COSV52347140; called by muse, mutect2, varscan2
- ADAM12 | c.1199T>C p.L400S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64108687; called by muse, mutect2, varscan2
- ADAM12 | c.190C>A p.H64N | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64108695; called by muse, varscan2
- ADAM15 | c.446G>T p.R149I | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV55060292; called by muse, mutect2, varscan2
- ADAM17 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 106/206 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60399609; called by muse, mutect2, varscan2
- ADAM18 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55849389; called by muse, mutect2, varscan2
- ADAM18 | c.1115T>G p.F372C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as COSV55849397; called by muse, mutect2, varscan2
- ADAM2 | c.2085C>A p.F695L | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.883); catalogued as COSV55863973; called by muse, mutect2, varscan2
- ADAM2 | c.1402A>C p.N468H | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1563343653, COSV55863980; called by mutect2, varscan2
- ADAM2 | c.704A>C p.N235T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55863987; called by muse, mutect2, varscan2
- ADAM20 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV56455339; called by muse, varscan2
- ADAM20 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV56455348; called by muse, varscan2
- ADAM21 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99960776; called by muse, mutect2, varscan2
- ADAM21 | c.901A>C p.N301H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV50797111; called by muse, mutect2, varscan2
- ADAM23 | c.1237G>T p.G413* | Nonsense Mutation (SNP) | VAF 67/141 reads (48%) | catalogued as COSV52208183; called by muse, mutect2, varscan2
- ADAM28 | c.260A>C p.Y87S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV56101752; called by muse, varscan2
- ADAM28 | c.312T>G p.D104E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV56101759; called by muse, mutect2, varscan2
- ADAM29 | c.1671G>T p.E557D | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.166); catalogued as rs1235028373, COSV63664020, COSV63664715; called by muse, mutect2, varscan2
- ADAM29 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63664722; called by muse, mutect2, varscan2
- ADAM30 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as rs149279290; called by muse, mutect2, varscan2
- ADAM33 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV62935207; called by muse, mutect2, varscan2
- ADAM7 | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV51541698, COSV99444989; called by muse, mutect2, varscan2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, mutect2, varscan2
- ADAMDEC1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as rs376286647, COSV56474636; called by muse, mutect2, varscan2
- ADAMTS1 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53171192; called by muse, mutect2, varscan2
- ADAMTS12 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61266201; called by muse, mutect2, varscan2
- ADAMTS12 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV61266212, COSV61267255; called by muse, mutect2, varscan2
- ADAMTS13 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV63021836; called by mutect2, varscan2
- ADAMTS14 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776328715, COSV64600156; called by muse, mutect2, varscan2
- ADAMTS16 | c.3262C>T p.R1088* | Nonsense Mutation (SNP) | VAF 34/69 reads (49%) | catalogued as COSV56993855; called by muse, mutect2, varscan2
- ADAMTS20 | c.5329C>A p.Q1777K | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV101238652, COSV67133592, COSV67135584; called by muse, mutect2, varscan2
- ADAMTS20 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143824237; called by muse, mutect2, varscan2
- ADAMTS3 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 53/130 reads (41%) | catalogued as COSV54394586; called by muse, mutect2, varscan2
- ADAMTS6 | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as COSV66858386; called by muse, mutect2, varscan2
- ADAMTS6 | c.634T>G p.F212V | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV66861151; called by muse, mutect2, varscan2
- ADCY10 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.478); catalogued as rs774828588, COSV63240542; called by muse, mutect2
- ADCY10 | c.1786C>A p.L596I | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV63241661; called by muse, mutect2, varscan2
- ADCY10 | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1415277884, COSV100896638, COSV63240393; called by muse, mutect2, varscan2
- ADCY10 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV63241674, COSV63242035; called by muse, mutect2, varscan2
- ADCY2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369487048, COSV57871248; called by muse, mutect2, varscan2
- ADCY2 | c.2496C>A p.F832L | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV57879126; called by muse, mutect2, varscan2
- ADCY8 | c.2369T>G p.F790C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV53912611; called by muse, mutect2, varscan2
- ADCY8 | c.1213A>T p.I405F | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53912627; called by muse, mutect2, varscan2
- ADCY9 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV53570707, COSV53577035; called by muse, mutect2, varscan2
- ADCY9 | c.1772T>C p.F591S | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV53577043; called by muse, mutect2, varscan2
- ADCY9 | c.1019G>T p.R340I | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs780726526, COSV99569707; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.329-1G>A p.X110_splice | Splice Site (SNP) | VAF 92/187 reads (49%) | catalogued as COSV58444477; called by muse, mutect2, varscan2
- ADD3 | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53323221; called by muse, mutect2, varscan2
- ADGRA3 | c.2378A>C p.K793T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51564265; called by muse, varscan2
- ADGRB1 | c.2509A>G p.S837G | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV60098550; called by muse, mutect2, varscan2
- ADGRB3 | c.163T>C p.C55R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV65401827; called by muse, mutect2, varscan2
- ADGRB3 | c.2737A>C p.I913L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1186877223, COSV53249316; called by muse, mutect2, varscan2
- ADGRB3 | c.3160C>A p.L1054I | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV53249325; called by muse, mutect2, varscan2
- ADGRB3 | c.3844T>C p.Y1282H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53249335; called by muse, mutect2, varscan2
- ADGRB3 | c.4199G>T p.R1400I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53249350; called by muse, mutect2, varscan2
- ADGRB3 | c.4436A>G p.Y1479C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV53249368, COSV99485766; called by muse, mutect2, varscan2
- ADGRD1 | c.955A>G p.N319D | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV55455785; called by muse, mutect2
- ADGRD1 | c.967-1G>T p.X323_splice | Splice Site (SNP) | VAF 26/209 reads (12%) | catalogued as COSV55443987, COSV55456936; called by muse, mutect2, varscan2
- ADGRE1 | c.239-1G>T p.X80_splice | Splice Site (SNP) | VAF 27/67 reads (40%) | catalogued as COSV51677018; called by muse, mutect2, varscan2
- ADGRE2 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV100215887; called by muse, mutect2
- ADGRF1 | c.2466T>G p.I822M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99347143; called by muse, mutect2
- ADGRF1 | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.403); catalogued as rs753292636, COSV51944555, COSV51946042; called by muse, mutect2, varscan2
- ADGRF2 | c.1619C>T p.A540V (on ENST00000296862 / NM_001368115.2; = p.A472V on NM_153839.7) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1310459307, COSV57289123, COSV99731349; called by muse, mutect2, varscan2
- ADGRF5 | c.3816+1G>A p.X1272_splice | Splice Site (SNP) | VAF 57/146 reads (39%) | catalogued as COSV51935618; called by muse, mutect2, varscan2
- ADGRF5 | c.1390A>C p.K464Q | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV51935631; called by muse, varscan2
- ADGRG2 | c.2451G>T p.K817N (on ENST00000379869 / NM_001079858.3; = p.K814N on NM_005756.4) | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV61339753; called by muse, varscan2
- ADGRG2 | c.2441G>A p.R814Q (on ENST00000379869 / NM_001079858.3; = p.R811Q on NM_005756.4) | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs184370776, COSV61337768, COSV61340199; called by muse, varscan2
- ADGRG4 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV54959031; called by muse, mutect2, varscan2
- ADGRG4 | c.2799T>G p.F933L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54959036; called by muse, mutect2, varscan2
- ADGRG4 | c.3129T>G p.F1043L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV54959044; called by muse, mutect2, varscan2
- ADGRG4 | c.6830C>A p.S2277Y | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.345); catalogued as COSV54951513; called by muse, mutect2, varscan2
- ADGRG4 | c.7490T>G p.I2497R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV54959067; called by muse, mutect2, varscan2
- ADGRG6 | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs748239263, COSV51592160; called by muse, mutect2, varscan2
- ADGRG6 | c.1359C>A p.I453= | Splice Region (SNP) | VAF 21/50 reads (42%) | catalogued as COSV51594452; called by muse, mutect2, varscan2
- ADGRG7 | c.1063A>T p.N355Y | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV56297960; called by muse, mutect2, varscan2
- ADGRL4 | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV66062341; called by muse, mutect2, varscan2
- ADGRV1 | c.5408C>A p.S1803Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.979); catalogued as rs371348667, COSV67990524; called by muse, mutect2, varscan2
- ADGRV1 | c.7136G>A p.G2379E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as COSV101315722; called by muse, mutect2, varscan2
- ADGRV1 | c.11956G>T p.E3986* | Nonsense Mutation (SNP) | VAF 96/196 reads (49%) | catalogued as COSV67987903; called by muse, mutect2, varscan2
- ADH1C | c.1079T>G p.F360C | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV72624870; called by muse, mutect2, varscan2
- ADH7 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs146508025; called by muse, mutect2, varscan2
- ADH7 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs549028723, COSV52923136; called by muse, varscan2
- ADPRHL1 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62910375; called by muse, mutect2, varscan2
- ADRA2B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787168; called by muse, mutect2, varscan2
- ADRB2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60005704; called by muse, mutect2, varscan2
- ADSS1 | c.1295T>C p.F432S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV58274233; called by muse, mutect2, varscan2
- ADTRP | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as rs760353796, COSV57644022; called by muse, mutect2, varscan2
- AFDN | c.301+1G>A p.X101_splice | Splice Site (SNP) | VAF 35/93 reads (38%) | catalogued as COSV60047120; called by muse, mutect2, varscan2
- AFDN | c.4931G>T p.R1644L (on ENST00000447894 / NM_001366320.1; = p.R1642L on NM_001040000.3) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV60047174; called by muse, mutect2, varscan2
- AFDN | c.5293C>T p.R1765W (on ENST00000447894 / NM_001366320.1; = p.R1684W on NM_001207008.1) | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs540701101, COSV63538401; called by muse, mutect2, varscan2
- AFF1 | c.2207A>G p.K736R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV57120990; called by muse, mutect2, varscan2
- AFF2 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as COSV60669159; called by muse, varscan2
- AFF2 | c.2120C>A p.S707Y | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53990026; called by muse, mutect2, varscan2
- AFF2 | c.2906C>T p.S969L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.137); catalogued as rs782779717, COSV53975111; called by muse, mutect2, varscan2
- AFF2 | c.3273G>T p.E1091D | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.193); catalogued as COSV53994174; called by muse, mutect2, varscan2
- AFF2 | c.3500A>G p.Y1167C | Missense Mutation (SNP) | VAF 94/185 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53994202; called by muse, mutect2, varscan2
- AFM | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56920642; called by muse, mutect2, varscan2
- AGAP1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs750448988, COSV58329822; called by muse, mutect2, varscan2
- AGAP6 | c.1337C>T p.S446L (on ENST00000374056 / NM_001365867.1; = p.S469L on NM_001077665.2) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs782281904, COSV65017834; called by muse, mutect2, varscan2
- AGBL4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748307842, COSV61891203; called by muse, mutect2, varscan2
- AGBL5 | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 114/246 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59936287, COSV59936860; called by muse, mutect2, varscan2
- AGK | c.984A>C p.E328D | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1395081309; called by muse, mutect2
- AGL | c.2506G>T p.E836* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV54054022; called by muse, mutect2, varscan2
- AGMO | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61106127; called by muse, mutect2, varscan2
- AGO1 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64595188; called by muse, mutect2, varscan2
- AGO3 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55794226; called by muse, mutect2, varscan2
- AGR2 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV101290810, COSV68597624; called by muse, mutect2, varscan2
- AGTPBP1 | c.1241G>A p.R414Q (on ENST00000357081 / NM_001330701.2; = p.R374Q on NM_015239.2) | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100429369, COSV61270313; called by muse, mutect2, varscan2
- AGTR2 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV64156612, COSV64157044; called by muse, mutect2, varscan2
- AGTR2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs1163188247, COSV64156615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGTRAP | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58668955; called by muse, mutect2, varscan2
- AGXT2 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51487506, COSV51490159; called by muse, mutect2, varscan2
- AHNAK | c.5290T>G p.L1764V | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV57217493; called by muse, mutect2, varscan2
- AHNAK | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 93/201 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as rs763485398, COSV57217512; called by muse, mutect2, varscan2
- AHNAK2 | c.17066A>G p.K5689R | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV60918702; called by muse, mutect2, varscan2
- AHNAK2 | c.14380A>C p.K4794Q | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); catalogued as COSV60918718; called by muse, mutect2, varscan2
- AHNAK2 | c.10430A>C p.K3477T | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60918727; called by muse, mutect2, varscan2
- AHNAK2 | c.6980C>A p.S2327* | Nonsense Mutation (SNP) | VAF 84/181 reads (46%) | catalogued as COSV100316817; called by muse, mutect2
- AIFM1 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs760430538, COSV54855574; called by muse, mutect2, varscan2
- AIM2 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.82); PolyPhen benign (0.172); catalogued as COSV63700286; called by muse, mutect2, varscan2
- AK7 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV50873665; called by muse, mutect2, varscan2
- AK8 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV53752826; called by muse, mutect2, varscan2
- AK9 | c.2774G>T p.R925I | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100393385, COSV58138579; called by muse, mutect2, varscan2
- AKAP10 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 88/214 reads (41%) | catalogued as COSV56731702; called by muse, mutect2, varscan2
- AKAP13 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as COSV63461533; called by muse, mutect2, varscan2
- AKAP13 | c.2233G>T p.D745Y | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs747774362, COSV63453850; called by muse, mutect2, varscan2
- AKAP13 | c.2381A>C p.E794A | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV63461545; called by muse, mutect2, varscan2
- AKAP3 | c.2104G>T p.D702Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57417713; called by muse, mutect2, varscan2
- AKAP4 | c.2354A>C p.Q785P | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV62074720; called by muse, mutect2, varscan2
- AKAP6 | c.1061A>G p.H354R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs1276437871, COSV55217882; called by muse, mutect2, varscan2
- AKAP9 | c.8053G>T p.E2685* (on ENST00000359028; = p.E2661* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV62349470; called by muse, mutect2, varscan2
- AKNA | c.2516C>A p.S839Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.456); catalogued as COSV56313358; called by muse, mutect2, varscan2
- AKNAD1 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.911); catalogued as COSV62199668; called by muse, varscan2
- AKNAD1 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62199681; called by muse, mutect2, varscan2
- AKR1C4 | c.61T>G p.F21V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54123808; called by muse, mutect2, varscan2
- AKR1C4 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV54123816; called by muse, mutect2, varscan2
- AKT3 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV55612501, COSV99796232; called by muse, mutect2, varscan2
- AKTIP | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs141560947; called by muse, mutect2, varscan2
- AL136295.1 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV99841760; called by muse, mutect2
- AL592490.1 | c.2017T>G p.W673G | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.675); catalogued as COSV69426698; called by muse, mutect2, varscan2
- AL592490.1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425975; called by muse, mutect2, varscan2
- ALB | c.161A>T p.Y54F | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV55739085; called by muse, varscan2
- ALB | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV55739096; called by muse, mutect2, varscan2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 47/120 reads (39%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH3A2 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51567270; called by muse, mutect2, varscan2
- ALDH3A2 | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51567286; called by muse, mutect2, varscan2
- ALG10 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 121/248 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs550400857, COSV56792889; called by muse, mutect2, varscan2
- ALG10B | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as COSV58142382; called by muse, mutect2, varscan2
- ALG13 | c.1523G>T p.R508I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV52640520; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALG13 | c.3046T>G p.Y1016D | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV52640553; called by muse, varscan2
- ALKBH3 | c.459C>T p.H153= | Splice Region (SNP) | VAF 64/144 reads (44%) | catalogued as rs1268112542, COSV57024750; called by muse, mutect2, varscan2
- ALMS1 | c.9654T>G p.I3218M | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52512729; called by muse, mutect2, varscan2
- ALOX5 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs989659749, COSV65551915; called by muse, mutect2, varscan2
- ALOXE3 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 64/156 reads (41%) | catalogued as COSV59076261, COSV59077184; called by muse, mutect2, varscan2
- ALPK1 | c.484T>G p.L162V | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs1447951650, COSV51586578; called by muse, mutect2, varscan2
- ALPK1 | c.1310T>C p.F437S | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV51586593; called by muse, mutect2, varscan2
- ALPK1 | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1190451372, COSV51586602; called by muse, mutect2, varscan2
- ALPK2 | c.5498G>T p.R1833I | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64493973; called by muse, varscan2
- ALPK2 | c.5250G>T p.K1750N | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV64491095; called by muse, mutect2, varscan2
- ALPK2 | c.2747A>C p.N916T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV64493983; called by muse, mutect2, varscan2
- ALYREF | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58668682; called by muse, mutect2, varscan2
- AMBRA1 | c.2215G>T p.D739Y (on ENST00000458649 / NM_001367468.1; = p.D649Y on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV54056838; called by muse, mutect2, varscan2
- AMER1 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV57659668; called by muse, mutect2, varscan2
- AMER2 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV63438354; called by muse, mutect2, varscan2
- AMER3 | c.477C>A p.C159* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV58467725; called by muse, mutect2, varscan2
- AMFR | c.1378A>C p.M460L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV51922333; called by muse, mutect2, varscan2
- AMOT | c.3020C>T p.A1007V (on ENST00000371959 / NM_001113490.1; = p.A598V on NM_133265.3) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV59064797; called by muse, mutect2, varscan2
- AMOT | c.1540C>T p.R514C (on ENST00000371959 / NM_001113490.1; = p.R105C on NM_133265.3) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142235994, COSV59061402; called by muse, mutect2, varscan2
- AMOTL1 | c.1659C>A p.F553L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs866769079, COSV58565783, COSV58567541; called by muse, mutect2, varscan2
- AMPD1 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV62416746; called by muse, mutect2, varscan2
- AMPH | c.306T>G p.C102W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57745772; called by muse, mutect2, varscan2
- AMY2A | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV70214607; called by muse, mutect2, varscan2
- ANAPC1 | c.5302C>A p.L1768M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as COSV61976893; called by mutect2, varscan2
- ANAPC1 | c.3227G>A p.R1076Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61976899; called by muse, mutect2, varscan2
- ANAPC1 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 139/289 reads (48%) | catalogued as COSV61976907; called by muse, mutect2, varscan2
- ANAPC4 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as rs866765051, COSV100194212, COSV59544708; called by muse, mutect2, varscan2
- ANAPC5 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55843265; called by muse, mutect2, varscan2
- ANAPC5 | c.725A>C p.N242T | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV55843278; called by muse, mutect2, varscan2
- ANGEL2 | c.788T>G p.F263C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64737538; called by muse, mutect2, varscan2
- ANK2 | c.7840G>T p.E2614* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV52155032; called by muse, mutect2, varscan2
- ANK2 | c.8882C>A p.S2961Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV52160031, COSV52162552; called by muse, mutect2, varscan2
- ANK2 | c.11259C>A p.F3753L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.05); catalogued as COSV52145235; called by muse, mutect2, varscan2
- ANK3 | c.8349T>A p.D2783E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV55063881; called by muse, mutect2, varscan2
- ANK3 | c.3298T>G p.L1100V (on ENST00000280772 / NM_001320874.2; = p.L234V on NM_001149.3) | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV55063892; called by muse, mutect2, varscan2
- ANKAR | c.2760A>C p.Q920H | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55614168; called by muse, mutect2, varscan2
- ANKAR | c.3275G>T p.R1092I | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.367); catalogued as COSV55614188; called by muse, mutect2, varscan2
- ANKDD1A | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.328); catalogued as rs1465711414, COSV63087541; called by muse, mutect2, varscan2
- ANKEF1 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745650843, COSV65692434; called by muse, mutect2, varscan2
- ANKFY1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs903431173, COSV58915656; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2443G>T p.D815Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV51850559; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3563A>C p.K1188T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51850573, COSV99783772; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7135G>T p.G2379* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV51850588; called by muse, mutect2, varscan2
- ANKRD11 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs1323661347, COSV56359151; called by muse, mutect2
- ANKRD11 | c.3097A>G p.S1033G | Missense Mutation (SNP) | VAF 158/422 reads (37%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV56363290; called by muse, mutect2, varscan2
- ANKRD11 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs145678880; called by muse, mutect2, varscan2
- ANKRD13B | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67474024; called by muse, mutect2, varscan2
- ANKRD16 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 76/188 reads (40%) | catalogued as rs774806484, COSV51947720, COSV99510373; called by muse, varscan2
- ANKRD17 | c.3910C>A p.L1304I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58222588; called by muse, mutect2, varscan2
- ANKRD17 | c.1892G>T p.R631I | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV58222597; called by muse, mutect2, varscan2
- ANKRD24 | c.1398G>T p.E466D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53671982; called by mutect2, varscan2
- ANKRD24 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as rs979241268, COSV53671997; called by muse, mutect2, varscan2
- ANKRD26 | c.3085G>T p.E1029* | Nonsense Mutation (SNP) | VAF 92/224 reads (41%) | catalogued as COSV65776219; called by muse, mutect2, varscan2
- ANKRD26 | c.2780A>C p.E927A | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65776229; called by muse, mutect2, varscan2
- ANKRD26 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 146/343 reads (43%) | catalogued as COSV65775303; called by muse, mutect2, varscan2
- ANKRD27 | c.1670G>T p.R557I | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV60132738; called by muse, mutect2, varscan2
- ANKRD28 | c.1174C>A p.L392I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV67518194; called by mutect2, varscan2
- ANKRD30A | c.2031A>C p.Q677H (on ENST00000611781; = p.Q621H on NM_052997.2) | Missense Mutation (SNP) | VAF 144/332 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV64613100; called by muse, mutect2, varscan2
- ANKRD30A | c.2491A>C p.K831Q (on ENST00000611781; = p.K775Q on NM_052997.2) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.099); catalogued as COSV64613109; called by muse, mutect2, varscan2
- ANKRD30A | c.3028A>C p.K1010Q (on ENST00000611781; = p.K954Q on NM_052997.2) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV64605511; called by muse, varscan2
- ANKRD30A | c.3066A>C p.Q1022H (on ENST00000611781; = p.Q966H on NM_052997.2) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV64613124; called by muse, varscan2
- ANKRD30A | c.3235G>T p.E1079* (on ENST00000611781; = p.E1023* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV64613134; called by mutect2, varscan2
- ANKRD42 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV52616503; called by muse, mutect2, varscan2
- ANKS1A | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV64461701; called by muse, mutect2, varscan2
- ANKS6 | c.1585G>T p.G529* | Nonsense Mutation (SNP) | VAF 61/167 reads (37%) | catalogued as COSV62050791; called by muse, mutect2, varscan2
- ANKZF1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs376160430; called by muse, mutect2, varscan2
- ANO1 | c.1105A>C p.M369L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV60285932; called by muse, mutect2, varscan2
- ANO1 | c.1357C>A p.H453N | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV60285948; called by muse, mutect2, varscan2
- ANO2 | c.2909G>A p.R970Q (on ENST00000356134 / NM_001278597.3; = p.R974Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs201987081, COSV59006793; called by muse, mutect2, varscan2
- ANO2 | c.2817G>T p.K939N (on ENST00000356134 / NM_001278597.3; = p.K943N on NM_001278596.3) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as COSV59028642; called by muse, mutect2, varscan2
- ANO2 | c.1814A>G p.K605R (on ENST00000356134 / NM_001278597.3; = p.K609R on NM_001278596.3) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV59028694; called by muse, mutect2, varscan2
- ANO2 | c.994G>T p.E332* (on ENST00000356134 / NM_001278597.3; = p.E336* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 44/114 reads (39%) | catalogued as COSV59028721; called by muse, mutect2, varscan2
- ANO3 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1230243991, COSV56792990; called by muse, mutect2, varscan2
- ANO4 | c.2152C>A p.L718I (on ENST00000392977 / NM_001286615.2; = p.L683I on NM_178826.4) | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.429); catalogued as COSV54600049; called by muse, mutect2, varscan2
- ANO5 | c.2675C>A p.S892Y | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV61086353; called by muse, mutect2, varscan2
- ANO6 | c.1611C>T p.F537= | Splice Region (SNP) | VAF 30/71 reads (42%) | catalogued as rs536008906, COSV57662793; called by muse, mutect2, varscan2
- ANO7 | c.2523G>T p.Q841H (on ENST00000274979; = p.Q787H on NM_001370694.2) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.571); catalogued as COSV51473405, COSV51476015; called by muse, mutect2, varscan2
- ANOS1 | c.1456T>G p.Y486D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV52921608; called by muse, mutect2, varscan2
- ANP32B | c.202A>C p.K68Q | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59586956; called by muse, mutect2, varscan2
- ANTXR2 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.078); catalogued as COSV56316450; called by muse, mutect2, varscan2
- ANXA10 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 253/547 reads (46%) | catalogued as rs374810057; called by muse, mutect2, varscan2
- ANXA6 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100636908; called by muse, mutect2
- AOC2 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs753613470, COSV53199641; called by muse, mutect2, varscan2
- AOC2 | c.2160C>A p.Y720* (on ENST00000253799 / NM_009590.4; = p.Y693* on NM_001158.5) | Nonsense Mutation (SNP) | VAF 54/115 reads (47%) | catalogued as COSV53827392; called by muse, mutect2, varscan2
- AOX1 | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs767970704, COSV65982275; called by muse, mutect2, varscan2
- AOX1 | c.2847+2T>C p.X949_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | catalogued as COSV65982281; called by muse, mutect2, varscan2
- AP002512.3 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.39); catalogued as rs1326016320, COSV56565765; called by muse, mutect2, varscan2
- AP1B1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1336656142, COSV58015058; called by muse, varscan2
- AP1G1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV55490927; called by muse, mutect2, varscan2
- AP1G1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 55/124 reads (44%) | catalogued as COSV55490960; called by muse, mutect2, varscan2
- AP3B1 | c.2941G>T p.E981* | Nonsense Mutation (SNP) | VAF 34/92 reads (37%) | catalogued as COSV54886013, COSV54888234; called by muse, mutect2, varscan2
- AP3B1 | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV54886024; called by muse, mutect2, varscan2
- AP3B2 | c.2504C>T p.S835F (on ENST00000261722; = p.S829F on NM_004644.5) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1164886541, COSV55610624; called by muse, mutect2, varscan2
- AP3B2 | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as COSV55610638; called by muse, varscan2
- AP3B2 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55610575, COSV55610646; called by muse, varscan2
- AP4E1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as COSV55917838; called by muse, mutect2, varscan2
- APBB1 | c.2108A>C p.K703T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV54968693; called by muse, mutect2, varscan2
- APC | c.5758C>T p.R1920* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as COSV57330105; called by muse, mutect2, varscan2
- APC | c.6502C>A p.L2168I | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV57335731; called by muse, mutect2, varscan2
- APOB | c.13355T>A p.L4452H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as rs1240567438, COSV51940089; called by muse, mutect2, varscan2
- APOB | c.10566T>G p.N3522K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99264837; called by muse, mutect2
- APOB | c.9307T>G p.S3103A | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51940096; called by muse, mutect2, varscan2
- APOB | c.8209C>A p.H2737N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); catalogued as COSV51940107; called by muse, mutect2, varscan2
- APOB | c.7850T>G p.F2617C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51928585; called by muse, mutect2
- APOB | c.3974C>A p.S1325Y | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51940116; called by muse, mutect2, varscan2
- APOH | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 72/151 reads (48%) | catalogued as COSV52772766, COSV52773198; called by muse, mutect2, varscan2
- APOH | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 72/182 reads (40%) | catalogued as COSV52773206, COSV52775103; called by muse, mutect2, varscan2
- APOL3 | c.384G>T p.K128N (on ENST00000349314 / NM_145640.2; = p.K57N on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV62579121, COSV62580060; called by muse, mutect2, varscan2
- APOL6 | c.126T>G p.F42L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480570400, COSV68749563; called by muse, varscan2
- APP | c.1473C>A p.F491L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV61000024; called by muse, mutect2, varscan2
- APP | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV60995467; called by muse, mutect2, varscan2
- AQP1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1401166675, COSV61267058; called by muse, mutect2, varscan2
- AQP11 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57992610; called by muse, mutect2, varscan2
- AQP9 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV54967982; called by muse, mutect2, varscan2
- AQR | c.3586T>C p.Y1196H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV50037648; called by muse, mutect2, varscan2
- AQR | c.2976A>C p.E992D | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV50037698; called by muse, mutect2, varscan2
- AR | c.2694G>T p.E898D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65956488, COSV65958458; called by muse, mutect2, varscan2
- ARAF | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1398289359, COSV51693300; called by muse, mutect2, varscan2
- ARAP2 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV58282405; called by muse, mutect2, varscan2
- AREL1 | c.333T>G p.I111M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.49); catalogued as COSV62666859; called by muse, varscan2
- ARFGAP1 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs200768802, COSV62262582; called by muse, mutect2, varscan2
- ARFGEF1 | c.5405T>G p.F1802C | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51586390; called by muse, mutect2, varscan2
- ARFGEF1 | c.4033C>T p.R1345* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs146133956, COSV51605657; called by mutect2, varscan2
- ARFGEF1 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 60/134 reads (45%) | catalogued as COSV51610855; called by muse, mutect2, varscan2
- ARFGEF1 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV51602242; called by muse, mutect2, varscan2
- ARFGEF2 | c.4677G>T p.L1559F | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64213022; called by muse, mutect2, varscan2
- ARGFX | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 76/170 reads (45%) | catalogued as rs267599565, COSV57682562; called by muse, mutect2, varscan2
- ARHGAP11A | c.932G>T p.R311I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs372419991; called by muse, mutect2, varscan2
- ARHGAP11A | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 26/50 reads (52%) | catalogued as rs1487117985, COSV64381180; called by muse, mutect2, varscan2
- ARHGAP11A | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV55706939; called by muse, mutect2, varscan2
- ARHGAP11A | c.2151C>A p.F717L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55706944; called by muse, mutect2, varscan2
- ARHGAP18 | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1403798551, COSV63764803; called by muse, mutect2, varscan2
- ARHGAP18 | c.1152T>G p.F384L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63764809; called by muse, mutect2, varscan2
- ARHGAP19 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 99/234 reads (42%) | catalogued as COSV57392369, COSV57392530, COSV57393591; called by muse, mutect2, varscan2
- ARHGAP19 | c.520A>C p.N174H | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.133); catalogued as COSV57393610; called by muse, mutect2, varscan2
- ARHGAP19 | c.403+1G>T p.X135_splice | Splice Site (SNP) | VAF 39/100 reads (39%) | catalogued as COSV57393616; called by muse, mutect2, varscan2
- ARHGAP20 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 29/56 reads (52%) | catalogued as rs751094122, COSV52808873; called by muse, mutect2, varscan2
- ARHGAP20 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs377077772, COSV52817761; called by muse, mutect2, varscan2
- ARHGAP21 | c.1033T>G p.L345V | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as COSV57607090; called by muse, mutect2, varscan2
- ARHGAP28 | c.1334T>G p.F445C (on ENST00000383472 / NM_001366230.1; = p.F286C on NM_001010000.3) | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51640049; called by muse, mutect2, varscan2
- ARHGAP29 | c.2443T>G p.F815V | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV53113245; called by muse, mutect2, varscan2
- ARHGAP30 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as COSV63517218; called by muse, mutect2, varscan2
- ARHGAP32 | c.4772C>A p.S1591Y (on ENST00000310343 / NM_001378025.1; = p.S1242Y on NM_014715.4) | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV59850073; called by muse, mutect2, varscan2
- ARHGAP35 | c.40T>G p.Y14D | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68332581; called by muse, mutect2, varscan2
- ARHGAP35 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 36/73 reads (49%) | catalogued as rs1324454897, COSV68329190; called by muse, mutect2, varscan2
- ARHGAP36 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52268230; called by muse, mutect2, varscan2
- ARHGAP5 | c.2140C>A p.L714I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61536876, COSV61538587; called by muse, mutect2, varscan2
- ARHGAP6 | c.2009A>T p.D670V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57297661; called by muse, mutect2, varscan2
- ARHGAP6 | c.1204A>T p.S402C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57297469, COSV57297691; called by muse, mutect2, varscan2
- ARHGAP6 | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV57297725; called by muse, varscan2
- ARHGAP6 | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 157/343 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57297758; called by muse, mutect2, varscan2
- ARHGEF19 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs746448541, COSV54617190; called by muse, mutect2, varscan2
- ARHGEF26 | c.1313G>T p.R438I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62847825; called by muse, mutect2, varscan2
- ARHGEF26 | c.1398A>C p.K466N | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV62846714; called by muse, mutect2, varscan2
- ARHGEF26 | c.1831A>C p.K611Q | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as COSV62847853; called by muse, mutect2, varscan2
- ARHGEF26 | c.2392A>G p.R798G | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62847870; called by muse, mutect2, varscan2
- ARHGEF28 | c.2156C>A p.S719Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV55259750; called by muse, mutect2, varscan2
- ARHGEF3 | c.763T>G p.F255V | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56328214; called by muse, mutect2, varscan2
- ARHGEF38 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54443058; called by muse, mutect2, varscan2
- ARHGEF4 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs770753604, COSV58123831; called by muse, mutect2, varscan2
- ARHGEF6 | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 74/180 reads (41%) | catalogued as COSV51687430; called by muse, mutect2, varscan2
- ARHGEF6 | c.854T>C p.L285S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51692365; called by muse, mutect2, varscan2
- ARHGEF6 | c.827A>C p.N276T | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as COSV51692378; called by muse, mutect2, varscan2
- ARID1A | c.3959C>A p.S1320Y | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61380310; called by muse, varscan2
- ARID1A | c.6403A>G p.I2135V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.181); catalogued as COSV61380314; called by muse, mutect2, varscan2
- ARID2 | c.371T>G p.I124S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV57606817; called by muse, mutect2, varscan2
- ARID2 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.972); catalogued as COSV57606825; called by muse, mutect2, varscan2
- ARID4A | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1180580215, COSV62161861; called by muse, mutect2, varscan2
- ARID4A | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV62164572; called by muse, mutect2, varscan2
- ARID4B | c.3208G>T p.E1070* | Nonsense Mutation (SNP) | VAF 39/154 reads (25%) | catalogued as COSV51605481; called by muse, mutect2, varscan2
- ARID4B | c.2844T>G p.D948E | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV51605500; called by muse, mutect2, varscan2
- ARL13A | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV65880218; called by muse, mutect2, varscan2
- ARL13A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.235); catalogued as rs377660986, COSV65880221; called by muse, mutect2, varscan2
- ARL13A | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV65880222; called by muse, mutect2, varscan2
- ARL13B | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV100115312; called by muse, varscan2
- ARL4A | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV63319444; called by muse, mutect2, varscan2
- ARMC2 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 67/140 reads (48%) | catalogued as COSV64551636; called by muse, mutect2, varscan2
- ARMC3 | c.2362G>T p.G788* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV53063119; called by muse, mutect2, varscan2
- ARMC9 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.36); catalogued as COSV63021737; called by muse, mutect2, varscan2
- ARMCX1 | c.1236C>A p.F412L | Missense Mutation (SNP) | VAF 95/191 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100863170, COSV65705296; called by muse, mutect2, varscan2
- ARMCX2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs781783235, COSV57529674; called by muse, mutect2, varscan2
- ARMCX3 | c.908T>G p.L303R | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57870889; called by muse, varscan2
- ARMCX5-GPRASP2 | c.1529T>C p.F510S | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV63437952; called by muse, mutect2, varscan2
- ARMH4 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs142845597; called by muse, mutect2, varscan2
- ARNTL2 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV53824861; called by muse, mutect2, varscan2
- ARPP21 | c.835A>C p.K279Q | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV51800604; called by muse, mutect2, varscan2
- ARR3 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 58/107 reads (54%) | catalogued as COSV52104359; called by muse, varscan2
- ARRDC4 | c.641T>G p.I214S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51419544; called by muse, mutect2, varscan2
- ARSG | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1369350242, COSV71592584; called by muse, mutect2, varscan2
- ARSG | c.1047G>A p.W349* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV71593423; called by muse, mutect2, varscan2
- ARSH | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs907740496, COSV66963179; called by muse, mutect2, varscan2
- ARSL | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV66965403; called by muse, mutect2, varscan2
- ASAH2B | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV51767807, COSV99485879; called by muse, mutect2, varscan2
- ASAP1 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as rs768671699, COSV63050217; called by muse, mutect2, varscan2
- ASAP1 | c.914C>A p.S305Y | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV100727069; called by muse, varscan2
- ASB10 | c.853G>A p.A285T (on ENST00000420175 / NM_001142459.2; = p.A270T on NM_080871.4) | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs574153932, COSV51997183; called by muse, mutect2, varscan2
- ASB11 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV60355573; called by muse, mutect2, varscan2
- ASB11 | c.52T>C p.F18L | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.956); catalogued as COSV60355581; called by muse, mutect2, varscan2
- ASB12 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1298297861, COSV62856043; called by muse, mutect2, varscan2
- ASB17 | c.875A>C p.N292T | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV52410831; called by muse, mutect2, varscan2
- ASB17 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV52409620; called by mutect2, varscan2
- ASB3 | c.783-1G>T p.X261_splice | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as COSV55074944; called by muse, mutect2, varscan2
- ASB5 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV56671918; called by muse, mutect2, varscan2
- ASB6 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs370764640; called by muse, mutect2, varscan2
- ASCC1 | c.615G>T p.K205N (on ENST00000342444 / NM_001369085.1; = p.K177N on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299239064, COSV57725988; called by muse, varscan2
- ASCC2 | c.725T>G p.L242* | Nonsense Mutation (SNP) | VAF 61/116 reads (53%) | catalogued as COSV57074543; called by muse, mutect2, varscan2
- ASCC3 | c.3874C>A p.L1292I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV61230066; called by muse, mutect2, varscan2
- ASCC3 | c.2861T>G p.V954G | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV61230070; called by muse, mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASH1L | c.903T>G p.N301K | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100853305; called by muse, mutect2
- ASIC1 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57318566; called by muse, mutect2, varscan2
- ASIC3 | c.637A>C p.M213L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52506078; called by muse, mutect2, varscan2
- ASMTL | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.323); catalogued as rs5989854, COSV67244099; called by mutect2, varscan2
- ASPA | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV53980098, COSV53981551, COSV53982736; called by muse, mutect2, varscan2
- ASPM | c.9461G>T p.R3154I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV54132194; called by muse, varscan2
- ASPM | c.9368G>T p.R3123I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV54125112, COSV54132205; called by muse, mutect2, varscan2
- ASPM | c.8467A>C p.K2823Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.306); catalogued as COSV54132213; called by muse, mutect2, varscan2
- ASPM | c.5603G>T p.R1868I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs761106315, COSV54124517; called by muse, mutect2, varscan2
- ASPM | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs142655430, COSV54127984; called by muse, mutect2, varscan2
- ASPM | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54132233, COSV99660220; called by muse, mutect2, varscan2
- ASPM | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766198125, COSV54132241; called by muse, mutect2, varscan2
- ASPM | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV54132250; called by muse, mutect2, varscan2
- ASPN | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 94/215 reads (44%) | catalogued as COSV65016015; called by muse, mutect2, varscan2
- ASTE1 | c.1138C>A p.L380I | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53909034; called by muse, mutect2, varscan2
- ASTE1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as rs773437504, COSV53909044; called by muse, mutect2, varscan2
- ASXL1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139716375, COSV60103020; called by muse, varscan2
- ASXL1 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.287); catalogued as COSV60111064; called by muse, mutect2, varscan2
- ASXL3 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52469766, COSV52480405; called by muse, mutect2, varscan2
- ASXL3 | c.2037A>C p.E679D | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.053); catalogued as COSV52469789; called by muse, mutect2, varscan2
- ASXL3 | c.2936G>T p.R979I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV52469812; called by muse, mutect2, varscan2
- ASXL3 | c.4918A>C p.K1640Q | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV52469839; called by muse, mutect2, varscan2
- ASXL3 | c.5942C>T p.P1981L | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV52469854; called by muse, mutect2, varscan2
- ASZ1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52913632, COSV99498153; called by muse, mutect2, varscan2
- ASZ1 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV52913645; called by muse, mutect2, varscan2
- ATAD1 | c.881T>G p.F294C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV57757295; called by muse, mutect2, varscan2
- ATAD2 | c.2017A>C p.N673H | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV54882118; called by muse, mutect2, varscan2
- ATAD2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 59/151 reads (39%) | catalogued as COSV54876976; called by muse, mutect2, varscan2
- ATAD3B | c.363-2A>G p.X121_splice (on ENST00000308647; = p.X227_splice on NM_031921.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 57/114 reads (50%) | catalogued as rs771738989, COSV58021508; called by muse, mutect2, varscan2
- ATAD5 | c.4967T>G p.M1656R | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58975723; called by muse, mutect2, varscan2
- ATCAY | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs763099910, COSV56654027; called by muse, mutect2, varscan2
- ATF2 | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.188); catalogued as COSV51370549; called by muse, mutect2, varscan2
- ATF7IP | c.2210A>G p.K737R | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53772664; called by muse, mutect2, varscan2
- ATG16L1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs746840032, COSV61465102; called by muse, mutect2, varscan2
- ATG16L1 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 141/347 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61465288, COSV61466173; called by muse, mutect2, varscan2
- ATG2B | c.4977G>T p.M1659I | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as COSV55889442, COSV55890828; called by muse, mutect2, varscan2
- ATG2B | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1177438609, COSV63423882; called by muse, mutect2, varscan2
- ATG2B | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63423891; called by muse, mutect2, varscan2
- ATG2B | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.357); catalogued as rs778368919, COSV100737778, COSV63421927; called by muse, mutect2, varscan2
- ATG4C | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as rs759584462, COSV58606506; called by muse, mutect2, varscan2
- ATG4C | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58605034; called by muse, mutect2, varscan2
- ATL2 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as COSV60053120; called by muse, mutect2, varscan2
- ATM | c.1461T>G p.I487M | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53751251; called by muse, mutect2, varscan2
- ATM | c.6419T>G p.F2140C | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1297621371, COSV53751269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATMIN | c.1923C>A p.F641L | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV55146535; called by muse, mutect2, varscan2
- ATP10A | c.3559dup p.S1187Ffs*9 | Frame Shift Ins (INS) | VAF 28/80 reads (35%) | catalogued as rs1567295436; called by mutect2, pindel
- ATP10B | c.3910C>A p.L1304I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV59144695; called by muse, mutect2, varscan2
- ATP10D | c.98T>C p.L33S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99905443; called by muse, mutect2
- ATP10D | c.1055T>A p.F352Y | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV56708857; called by muse, varscan2
- ATP11B | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 41/86 reads (48%) | catalogued as COSV60029761; called by muse, mutect2, varscan2
- ATP11B | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV60026901; called by muse, mutect2, varscan2
- ATP11B | c.1348T>G p.L450V | Missense Mutation (SNP) | VAF 99/111 reads (89%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV60029778; called by muse, mutect2, varscan2
- ATP11B | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 37/72 reads (51%) | catalogued as COSV60029785, COSV60033853; called by muse, mutect2, varscan2
- ATP11B | c.2884C>A p.L962I | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as rs777376374, COSV60029804; called by muse, mutect2, varscan2
- ATP11C | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs959304549, COSV59561944; called by muse, mutect2, varscan2
- ATP11C | c.2181G>T p.K727N | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV59562556; called by muse, mutect2, varscan2
- ATP11C | c.1588A>C p.K530Q | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV59566805; called by muse, mutect2, varscan2
- ATP11C | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs768342557, COSV59561768; called by muse, mutect2, varscan2
- ATP11C | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59566866; called by muse, mutect2, varscan2
- ATP11C | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59559521; called by muse, mutect2, varscan2
- ATP12A | c.218A>C p.D73A | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV54518165; called by muse, mutect2, varscan2
- ATP12A | c.1958G>T p.S653I | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV54518177; called by muse, mutect2, varscan2
- ATP13A1 | c.3275A>C p.K1092T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV52287213; called by muse, mutect2, varscan2
- ATP13A3 | c.314A>C p.K105T | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as COSV55465749; called by muse, mutect2, varscan2
- ATP13A4 | c.2292G>T p.K764N | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV61321394; called by muse, mutect2, varscan2
- ATP13A5 | c.2833A>C p.M945L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV60870765; called by muse, mutect2, varscan2
- ATP13A5 | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 30/64 reads (47%) | catalogued as rs1352082779, COSV60866463; called by muse, mutect2
- ATP13A5 | c.1418G>T p.R473I | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100664961, COSV60872829; called by muse, mutect2
- ATP13A5 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.098); catalogued as COSV60870841; called by muse, mutect2, varscan2
- ATP1A1 | c.461G>T p.S154I | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55192046; called by muse, mutect2, varscan2
- ATP1A1 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV55192059; called by muse, mutect2, varscan2
- ATP1A2 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63404301; called by muse, mutect2, varscan2
- ATP1A2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375389965, COSV63404305; called by muse, mutect2, varscan2
- ATP1A2 | c.2589C>A p.F863L | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV100768099, COSV63403963, COSV63404309; called by muse, mutect2, varscan2
- ATP1A4 | c.2643G>T p.E881D | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.804); catalogued as COSV63626919; called by muse, mutect2, varscan2
- ATP2A1 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV63921468; called by muse, mutect2, varscan2
- ATP2A1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757752844, COSV63920538; called by muse, varscan2
- ATP2B1 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as COSV53806099; called by muse, mutect2, varscan2
- ATP2C1 | c.2100A>C p.K700N | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV60757964; called by muse, mutect2, varscan2
- ATP5F1A | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV56360771; called by muse, mutect2, varscan2
- ATP5F1A | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV56360788; called by muse, mutect2, varscan2
- ATP5F1B | c.1349A>G p.D450G | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV51638432; called by muse, mutect2, varscan2
- ATP5F1B | c.1276A>C p.K426Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.019); catalogued as COSV51638437; called by muse, mutect2, varscan2
- ATP5F1C | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 48/106 reads (45%) | catalogued as COSV59622038; called by muse, mutect2, varscan2
- ATP5MPL | c.131G>T p.R44I | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54603279; called by muse, mutect2, varscan2
- ATP6V0A1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 226/494 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV52874398; called by muse, mutect2, varscan2
- ATP6V0A1 | c.410A>C p.Q137P | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV52874410; called by muse, mutect2, varscan2
- ATP6V1A | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56360961, COSV56362916; called by muse, mutect2, varscan2
- ATP6V1B2 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as COSV52353985; called by muse, mutect2, varscan2
- ATP6V1C2 | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.412); catalogued as COSV55361472; called by muse, mutect2, varscan2
- ATP6V1E1 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV53658597; called by muse, mutect2, varscan2
- ATP6V1G1 | c.165C>A p.F55L | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV65014178, COSV99059956; called by muse, mutect2, varscan2
- ATP8A1 | c.2798C>A p.A933D | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV52538304; called by muse, mutect2, varscan2
- ATP8A2 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1349352729, COSV54945493; called by muse, mutect2, varscan2
- ATP8A2 | c.1802G>T p.R601I | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54958723; called by muse, mutect2, varscan2
- ATP8B1 | c.2872A>C p.N958H | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52177027; called by muse, mutect2, varscan2
- ATP8B3 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 55/136 reads (40%) | catalogued as COSV59544191; called by muse, mutect2, varscan2
- ATP8B4 | c.2764A>G p.M922V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.091); catalogued as COSV52717853; called by muse, mutect2, varscan2
- ATP9A | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs765812252, COSV100124686; called by muse, mutect2, varscan2
- ATP9A | c.1809G>T p.K603N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58768061; called by muse, mutect2, varscan2
- ATP9B | c.417A>C p.K139N | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56954067, COSV56959554; called by muse, mutect2, varscan2
- ATP9B | c.1202T>C p.F401S | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56954077; called by muse, mutect2, varscan2
- ATR | c.4507C>T p.R1503* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs754602382, COSV63387617; called by muse, mutect2, varscan2
- ATR | c.2705C>A p.S902Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.556); catalogued as COSV63384881, COSV63387625; called by mutect2, varscan2
- ATRX | c.4844A>G p.D1615G | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV64878309; called by muse, mutect2, varscan2
- ATRX | c.4450C>A p.L1484I | Missense Mutation (SNP) | VAF 153/398 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.1); catalogued as COSV64878316; called by muse, varscan2
- ATRX | c.3892G>T p.E1298* | Nonsense Mutation (SNP) | VAF 167/376 reads (44%) | catalogued as COSV64878328; called by muse, mutect2, varscan2
- ATRX | c.3070G>T p.E1024* | Nonsense Mutation (SNP) | VAF 51/103 reads (50%) | catalogued as COSV64878335; called by muse, mutect2, varscan2
- ATRX | c.2973A>C p.E991D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.018); catalogued as COSV100970482; called by muse, mutect2, varscan2
- ATRX | c.2599A>C p.N867H | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.121); catalogued as COSV64878343; called by muse, mutect2, varscan2
- ATRX | c.2407A>C p.I803L | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as COSV64878347; called by muse, mutect2, varscan2
- ATXN10 | c.1220T>G p.I407S | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV99426210; called by muse, mutect2
- ATXN2 | c.1083A>C p.K361N (on ENST00000550104; = p.K201N on NM_002973.4) | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV66483942; called by muse, mutect2, varscan2
- ATXN3 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as COSV61495928; called by muse, mutect2, varscan2
- ATXN3L | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); catalogued as rs1279979260, COSV66075300; called by muse, mutect2, varscan2
- ATXN3L | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV66075878; called by muse, mutect2, varscan2
- ATXN7L1 | c.72A>C p.Q24H | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV59493918; called by muse, mutect2, varscan2
- ATXN7L3 | c.545C>A p.P182H (on ENST00000389384 / NM_001382309.1; = p.P189H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as COSV60229092; called by muse, mutect2, varscan2
- AUP1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs755973491, COSV51206410; called by muse, mutect2, varscan2
- AURKA | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as COSV57168874, COSV57169563; called by muse, mutect2, varscan2
- AVIL | c.2347-2A>C p.X783_splice | Splice Site (SNP) | VAF 59/158 reads (37%) | catalogued as COSV57682328; called by muse, mutect2, varscan2
- AWAT2 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as COSV99339600; called by muse, mutect2
- AXDND1 | c.124A>C p.N42H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.459); catalogued as COSV62643992; called by muse, mutect2, varscan2
- AXDND1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs761222901, COSV62643998; called by muse, mutect2, varscan2
- AXDND1 | c.565T>G p.L189V | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62644005; called by muse, mutect2, varscan2
- AXDND1 | c.2829G>T p.E943D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62644010; called by muse, mutect2, varscan2
- AXL | c.1519C>T p.R507W (on ENST00000301178 / NM_021913.5; = p.R498W on NM_001699.6) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366012932, COSV56569928; called by muse, mutect2, varscan2
- AXL | c.1956C>A p.F652L (on ENST00000301178 / NM_021913.5; = p.F643L on NM_001699.6) | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56569934; called by muse, mutect2, varscan2
- AZIN2 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV53858333; called by muse, mutect2, varscan2
- B3GALT1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs144099662, COSV59908175; called by muse, mutect2, varscan2
- B3GALT2 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 56/132 reads (42%) | catalogued as COSV66464185; called by muse, mutect2, varscan2
- B3GALT2 | c.10T>C p.W4R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66464187; called by muse, mutect2, varscan2
- B3GAT1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV56998296; called by muse, mutect2, varscan2
- B3GLCT | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.34); catalogued as COSV58456078; called by muse, mutect2, varscan2
- B4GALNT3 | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56753986; called by muse, mutect2, varscan2
- B4GALT3 | c.1182A>G p.*394Wext*31 | Nonstop Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV60527420; called by muse, mutect2, varscan2
- B4GALT4 | c.313A>C p.N105H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63295985; called by muse, mutect2, varscan2
- BABAM2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 94/178 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs773629059, COSV59624470, COSV59630226, COSV59633919; called by muse, mutect2, varscan2
- BACH1 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1569017478, COSV54517670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BACH2 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV57596893; called by muse, mutect2, varscan2
- BAIAP2 | c.217+1G>C p.X73_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV58336658; called by muse, mutect2, varscan2
- BAIAP2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs144299493; called by muse, mutect2, varscan2
- BANK1 | c.1802C>A p.T601N | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as COSV100536152; called by muse, mutect2, varscan2
- BAZ1A | c.3695A>G p.D1232G | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV62410664; called by muse, mutect2, varscan2
- BAZ1A | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV62410667; called by muse, varscan2
- BAZ2B | c.6416T>G p.F2139C | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58603397; called by muse, mutect2, varscan2
- BAZ2B | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as rs1377012863, COSV58603408; called by muse, varscan2
- BBS12 | c.1631T>G p.F544C | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58562304; called by muse, mutect2, varscan2
- BBS2 | c.1391G>T p.R464I | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV55327047; called by muse, mutect2, varscan2
- BBS7 | c.2133C>A p.F711L | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52657287; called by muse, mutect2, varscan2
- BCHE | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100011955, COSV52259964; called by muse, mutect2
- BCL11A | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as COSV59632624; called by muse, mutect2, varscan2
- BCL2L15 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV63643101; called by muse, mutect2, varscan2
- BCLAF1 | c.2638A>C p.K880Q | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50358405; called by muse, mutect2, varscan2
- BCLAF1 | c.2111G>T p.R704I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50358406; called by muse, mutect2, varscan2
- BCLAF3 | c.2090T>C p.L697S (on ENST00000379682 / NM_001367774.1; = p.L668S on NM_198279.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100503256; called by muse, mutect2
- BCOR | c.5032C>T p.R1678C (on ENST00000378444 / NM_001123385.2; = p.R1644C on NM_017745.6) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs765528893, COSV60700046, COSV60710256; called by muse, mutect2, varscan2
- BCOR | c.2029G>T p.G677* | Nonsense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as COSV60710273; called by muse, mutect2, varscan2
- BCORL1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs138189929, COSV54390156; called by muse, mutect2, varscan2
- BCS1L | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1004879625, COSV55308087; called by muse, mutect2, varscan2
- BDH2 | c.670T>G p.L224V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56478807; called by muse, varscan2
- BDKRB1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.022); catalogued as rs780193100, COSV53706502; called by muse, varscan2
- BDKRB2 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV60015362; called by muse, mutect2, varscan2
- BDKRB2 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148172749; called by muse, mutect2, varscan2
- BDP1 | c.2173C>A p.L725I | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV62432140; called by muse, mutect2, varscan2
- BDP1 | c.4138C>A p.H1380N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV62432144; called by muse, mutect2, varscan2
- BDP1 | c.6818T>G p.V2273G | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV62432149; called by muse, mutect2, varscan2
- BEND2 | c.904T>G p.L302V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV66216189; called by muse, mutect2, varscan2
- BEND3 | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 172/409 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV64681401; called by muse, mutect2, varscan2
- BEND4 | c.1163T>C p.L388S | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV72469169; called by muse, mutect2, varscan2
- BEND4 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV72469065, COSV72469170; called by muse, varscan2
- BEND7 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV61989506; called by muse, mutect2, varscan2
- BEST2 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50367725; called by muse, mutect2, varscan2
- BEST3 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100437700; called by muse, mutect2
- BEST3 | c.1382C>A p.T461K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58302493; called by muse, mutect2, varscan2
- BEST3 | c.107T>C p.F36S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56994223, COSV56995038; called by muse, mutect2, varscan2
- BET1 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV55993042; called by muse, mutect2, varscan2
- BEX5 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 111/253 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV61328756; called by muse, mutect2, varscan2
- BFAR | c.1103T>C p.L368S | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55493480; called by muse, mutect2, varscan2
- BFSP1 | c.1923A>C p.E641D | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100925342; called by muse, mutect2
- BICD2 | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV63547971, COSV63550706; called by muse, mutect2, varscan2
- BICRAL | c.998T>G p.I333S | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV58406479; called by muse, mutect2, varscan2
- BIRC2 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 51/120 reads (43%) | catalogued as rs770159483, COSV57161003; called by muse, mutect2, varscan2
- BIRC2 | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57160988; called by muse, mutect2, varscan2
- BIRC6 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as COSV70201138; called by muse, mutect2, varscan2
- BIRC6 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.921); catalogued as COSV70195793, COSV70201145; called by muse, mutect2, varscan2
- BIRC6 | c.9589T>C p.W3197R | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70201151; called by muse, mutect2, varscan2
- BIRC6 | c.12286C>A p.Q4096K | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as COSV66042885; called by muse, mutect2, varscan2
- BIRC6 | c.13198C>T p.R4400W | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775855234, COSV70197809; called by muse, varscan2
- BIVM-ERCC5 | c.4063A>C p.K1355Q | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV63245478; called by muse, varscan2
- BIVM-ERCC5 | c.4315G>A p.D1439N | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748797643, COSV63245483; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4339A>C p.I1447L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV63245487; called by muse, mutect2, varscan2
- BLOC1S6 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 78/186 reads (42%) | catalogued as COSV55035585; called by muse, mutect2, varscan2
- BMP10 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV99770360; called by muse, mutect2
- BMP2 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV66578302; called by muse, mutect2, varscan2
- BMP4 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as COSV55416336; called by muse, mutect2, varscan2
- BMP5 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63704158; called by muse, mutect2, varscan2
- BMP6 | c.1205-1G>T p.X402_splice | Splice Site (SNP) | VAF 36/89 reads (40%) | catalogued as COSV51667077; called by muse, mutect2, varscan2
- BMPER | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs771286519, COSV51822299; called by muse, mutect2, varscan2
- BMPER | c.1769A>C p.E590A | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV51822320; called by muse, mutect2, varscan2
- BMPR1B | c.1257A>G p.I419M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as COSV52778811; called by muse, mutect2, varscan2
- BMPR2 | c.2912T>C p.I971T | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101001399; called by muse, mutect2
- BMS1 | c.1338A>C p.E446D | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100996644; called by muse, mutect2
- BMT2 | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV51777639; called by muse, mutect2, varscan2
- BMX | c.156A>C p.K52N | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59591836; called by muse, mutect2, varscan2
- BMX | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs767957207, COSV59591844; called by muse, mutect2, varscan2
- BNC1 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV61757888; called by muse, varscan2
- BNC2 | c.2060C>A p.S687Y | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV66149947; called by muse, mutect2, varscan2
- BNC2 | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV101032719; called by muse, mutect2, varscan2
- BNC2 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66149962; called by muse, mutect2, varscan2
- BNIP1 | c.170G>T p.R57I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51569987, COSV51570957; called by muse, mutect2, varscan2
- BNIP5 | c.1710C>A p.F570L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV71325606; called by muse, mutect2, varscan2
- BOD1L1 | c.5339C>A p.S1780Y | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50019903; called by muse, mutect2, varscan2
- BORA | c.1106A>C p.K369T (on ENST00000613797; = p.K294T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV64695417; called by muse, mutect2, varscan2
- BPIFA2 | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53611394; called by muse, mutect2, varscan2
- BPIFB1 | c.656T>G p.V219G | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV53607096; called by muse, mutect2, varscan2
- BPIFC | c.207A>C p.E69D | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV55913094; called by muse, mutect2, varscan2
- BPTF | c.7800A>C p.Q2600H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV58839645; called by muse, mutect2, varscan2
- BPTF | c.8530G>T p.D2844Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV58839655; called by muse, mutect2, varscan2
- BRAF | c.1870C>A p.L624I (on ENST00000288602 / NM_001374244.1; = p.L584I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV56096161, COSV56361615; called by muse, mutect2
- BRAF | c.1376C>A p.S459Y (on ENST00000288602 / NM_001374244.1; = p.S419Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56227205; called by muse, mutect2, varscan2
7,880 further variants in this file (6,283 protein-altering or splice-affecting, 1,415 silent, 182 other) are not listed here.
